Somatic mutation profile of tumor specimen MMRF_2082_1_BM_CD138pos (aliquot MMRF_2082_1_BM_CD138pos_T1_KHS5U_L08132) from MMRF case MMRF_2082, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,620 days).
Specimen MMRF_2082_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35df9dfc-8968-4644-a42d-ad28078fed6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2082_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2082_1_PB_Whole_C2_KHS5U_L08133; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/622aed60-0b4c-4d50-96cc-6435e9aa37e0

The open-access MAF lists 94 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 17, Intron 13, 5'UTR 9, Silent 8, Nonsense Mutation 4, 5'Flank 4, Frame Shift Del 3, RNA 3, 3'Flank 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCNJL | c.937T>A p.L313M | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as rs1390608389; called by muse, mutect2, varscan2
- CIP2A | c.1274C>T p.T425I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs764367066; called by muse, mutect2, varscan2
- FCAR | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs201648976, COSV62029164; called by muse, mutect2, varscan2
- HFM1 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1327294793; called by muse, mutect2, varscan2
- HSPB8 | c.126C>A p.D42E | Missense Mutation (SNP) | VAF 226/532 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.319); catalogued as rs763658767, COSV56137264; called by muse, mutect2, varscan2
- IGLL5 | c.124A>C p.M42L | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as rs550903741, COSV73251065, COSV73251253; called by muse, mutect2, varscan2
- IGLV3-1 | c.191T>A p.L64Q | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs371723569; called by muse, varscan2
- NUP98 | c.2198-6T>C | Splice Region (SNP) | VAF 12/26 reads (46%) | catalogued as COSV61439183; called by mutect2, varscan2
- PCDHAC2 | c.1951G>T p.E651* | Nonsense Mutation (SNP) | VAF 40/144 reads (28%) | catalogued as COSV53850555; called by muse, mutect2, varscan2
- PITX2 | c.452T>A p.L151Q (on ENST00000354925 / NM_001204397.1; = p.L158Q on NM_000325.6) | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60740208; called by muse, varscan2
- PKD2 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as rs1265006798; called by muse, mutect2
- PRAG1 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs782495223, COSV100421835; called by muse, varscan2
- RYR3 | c.7109G>A p.R2370H (on ENST00000389232; = p.R2371H on NM_001036.6) | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234585541, COSV101212486; called by muse, mutect2, varscan2
- SF3B1 | c.2179G>T p.V727L | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV100135201; called by muse, mutect2, varscan2
- TDRD10 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 40/69 reads (58%) | catalogued as rs141785787; called by muse, mutect2, varscan2
- UCHL3 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66460141; called by muse, mutect2, varscan2
- ADRA2B | c.89A>C p.N30T | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP6 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- CYLD | c.2165del p.N722Mfs*13 | Frame Shift Del (DEL) | VAF 31/46 reads (67%) | called by mutect2, pindel, varscan2
- DAB1 | c.628A>T p.I210F | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- DST | c.17763del p.E5922Kfs*24 (on ENST00000361203 / NM_001374722.1; = p.E3619Kfs*24 on NM_015548.5) | Frame Shift Del (DEL) | VAF 90/173 reads (52%) | called by mutect2, pindel, varscan2
- FASTKD1 | c.926T>C p.L309S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, varscan2
- HSPG2 | c.3314T>A p.I1105N | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- HTR3E | c.218C>T p.S73F (on ENST00000415389 / NM_001256613.1; = p.S88F on NM_182589.2) | Missense Mutation (SNP) | VAF 175/684 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- IRS2 | c.3893del p.G1298Afs*33 | Frame Shift Del (DEL) | VAF 49/127 reads (39%) | called by mutect2, pindel, varscan2
- IRS2 | c.3207_3215del p.G1070_Y1072del | In Frame Del (DEL) | VAF 27/74 reads (36%) | called by mutect2, pindel, varscan2
- KIZ | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 25/38 reads (66%) | called by muse, mutect2, varscan2
- LRRC8C | c.656A>G p.K219R | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- MACF1 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 92/182 reads (51%) | called by muse, mutect2, varscan2
- MAML3 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 139/303 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PGAP1 | c.1621G>T p.A541S | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PGAP1 | c.1620G>T p.Q540H | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- PRKCG | c.1560C>A p.D520E | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- SORBS1 | c.2128+1G>A p.X710_splice (on ENST00000361941 / NM_001034954.2; = p.X416_splice on NM_006434.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 16/23 reads (70%) | called by muse, mutect2, varscan2
- TRIML2 | c.1291T>A p.C431S | Missense Mutation (SNP) | VAF 144/370 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, varscan2
- VPS13C | c.266T>C p.L89P | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ZBED8 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ZNF292 | c.4111A>G p.R1371G | Missense Mutation (SNP) | VAF 119/355 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZNF770 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- FBN2 | c.5637C>T p.A1879= | Silent (SNP) | VAF 73/321 reads (23%) | catalogued as rs367620361; called by muse, mutect2, varscan2
- IGLL5 | c.123A>G p.P41= | Silent (SNP) | VAF 33/46 reads (72%) | catalogued as rs531175408, COSV73250509; called by muse, mutect2, varscan2
- ISLR | c.183G>T p.R61= | Silent (SNP) | VAF 72/267 reads (27%) | called by muse, mutect2, varscan2
- ITGA2 | c.3219T>C p.V1073= | Silent (SNP) | VAF 55/201 reads (27%) | called by muse, mutect2, varscan2
- NXN | c.1050G>A p.P350= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as rs551347236; called by muse, mutect2, varscan2
- PLEC | c.8580C>T p.P2860= (on ENST00000322810 / NM_201380.4; = p.P2750= on NM_000445.5) | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs375387549; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN7A | c.2622C>T p.C874= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- ZNF420 | c.1917T>G p.G639= | Silent (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- AL353747.1 | n.164C>T | RNA (SNP) | VAF 30/92 reads (33%) | catalogued as rs1434093440; called by muse, mutect2, varscan2
- ARHGAP27P2 | n.271G>T | RNA (SNP) | VAF 43/81 reads (53%) | catalogued as rs1403085050; called by muse, mutect2, varscan2
- BCL7A | chr12:122021532 G>C | 5'Flank (SNP) | VAF 35/78 reads (45%) | catalogued as COSV55846310; called by muse, mutect2, varscan2
- BMP3 | c.*2342T>C | 3'UTR (SNP) | VAF 78/161 reads (48%) | called by muse, mutect2, varscan2
- BMP6 | c.*1095G>A | 3'UTR (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- BOD1L1 | c.-114C>T | 5'UTR (SNP) | VAF 115/249 reads (46%) | called by muse, mutect2, varscan2
- BRWD1 | c.-267G>A | 5'UTR (SNP) | VAF 40/72 reads (56%) | catalogued as rs555425461; called by muse, mutect2, varscan2
- CALML4 | c.164-97G>A | Intron (SNP) | VAF 18/73 reads (25%) | called by muse, mutect2
- CERS4 | c.468+173A>C | Intron (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- DMC1 | c.-12C>T | 5'UTR (SNP) | VAF 127/279 reads (46%) | catalogued as rs745986107; called by muse, mutect2, varscan2
- DOCK8 | c.*593G>A | 3'UTR (SNP) | VAF 41/100 reads (41%) | called by muse, mutect2, varscan2
- EYS | c.1766+3654A>G | Intron (SNP) | VAF 62/103 reads (60%) | called by muse, mutect2
- FAM160A1 | c.-94G>T | 5'UTR (SNP) | VAF 122/288 reads (42%) | called by muse, mutect2, varscan2
- FRMD5 | chr15:44195272 del GTCTCCTCGG | 5'Flank (DEL) | VAF 30/163 reads (18%) | called by mutect2, pindel, varscan2
- GCNT2 | c.*808T>C | 3'UTR (SNP) | VAF 43/114 reads (38%) | catalogued as rs1429821223; called by muse, mutect2, varscan2
- GRAMD2B | c.128+11030A>G | Intron (SNP) | VAF 74/327 reads (23%) | called by muse, mutect2, varscan2
- HAS1 | c.1061+26G>T | Intron (SNP) | VAF 39/140 reads (28%) | catalogued as COSV55788959; called by muse, mutect2, varscan2
- HMGA2 | c.249+20353A>G | Intron (SNP) | VAF 33/61 reads (54%) | called by muse, mutect2, varscan2
- HSD17B3 | chr9:96302284 G>T | 5'Flank (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- IFT43 | c.215+122T>G | Intron (SNP) | VAF 13/23 reads (57%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.-52T>G | 5'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, varscan2
- JADE1 | c.*665T>C | 3'UTR (SNP) | VAF 212/475 reads (45%) | called by muse, mutect2, varscan2
- JCAD | c.*3277G>C | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- KLF14 | c.*245G>T | 3'UTR (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- LDHAL6B | c.*484G>A | 3'UTR (SNP) | VAF 34/129 reads (26%) | catalogued as rs755630591; called by muse, mutect2, varscan2
- LYPLA1 | c.*604C>G | 3'UTR (SNP) | VAF 31/238 reads (13%) | called by muse, mutect2, varscan2
- MACC1 | chr7:20137304 C>A | 3'Flank (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- MBNL1 | c.174+40491A>G | Intron (SNP) | VAF 64/194 reads (33%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851321 A>C | 5'Flank (SNP) | VAF 78/147 reads (53%) | catalogued as rs1440026460; called by muse, mutect2, varscan2
- MMP16 | c.*5054G>C | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- MRPL45 | c.*405T>A | 3'UTR (SNP) | VAF 55/106 reads (52%) | called by muse, mutect2, varscan2
- NARF | c.-43C>A | 5'UTR (SNP) | VAF 21/51 reads (41%) | catalogued as rs897261086; called by muse, mutect2, varscan2
- POLR2E | c.58-134C>T | Intron (SNP) | VAF 19/26 reads (73%) | called by muse, mutect2, varscan2
- PREX2 | c.*4976T>G | 3'UTR (SNP) | VAF 36/66 reads (55%) | called by muse, mutect2, varscan2
- RAD52 | c.467+249T>C | Intron (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- RASGRF1 | c.3542+1469G>T | Intron (SNP) | VAF 64/256 reads (25%) | catalogued as rs994939396; called by muse, mutect2, varscan2
- RCC1 | c.-261-666C>T | Intron (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.1459G>T | RNA (SNP) | VAF 26/341 reads (8%) | called by muse, mutect2
- RNF144B | c.-79T>C | 5'UTR (SNP) | VAF 44/128 reads (34%) | catalogued as rs1336800040; called by muse, mutect2, varscan2
- SEPTIN14 | c.*403G>A | 3'UTR (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- SERTM1 | c.*515T>C | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- TBC1D30 | c.*3711T>C | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- TBX20 | c.-354G>A | 5'UTR (SNP) | VAF 90/332 reads (27%) | called by muse, varscan2
- TMEM235 | c.-121A>T | 5'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- VGF | c.*180C>A | 3'UTR (SNP) | VAF 41/118 reads (35%) | called by muse, mutect2, varscan2
- WNK1 | c.6831+57del | Intron (DEL) | VAF 16/34 reads (47%) | called by mutect2, pindel, varscan2
- ZNF462 | c.*2520dup | 3'UTR (INS) | VAF 22/82 reads (27%) | catalogued as rs968644290; called by mutect2, varscan2
